MMRF case MMRF_1021 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9b5dbbf9-dbb3-45ce-985e-be18c763c172

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.1 years (19,778 days); ISS stage: I; Days to last known disease status: 1,932 days (5.3 years); Days to last follow up: 1,932 days (5.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 84 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 630 days (1.7 years); Days to treatment end: 825 days (2.3 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 844 days (2.3 years); Days to treatment end: 847 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 845 days (2.3 years); Days to treatment end: 848 days (2.3 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 847 days (2.3 years); Days to treatment end: 847 days (2.3 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 847 days (2.3 years); Days to treatment end: 848 days (2.3 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: Second line of therapy; Days to treatment start: 849 days (2.3 years); Days to treatment end: 849 days (2.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -28 (ECOG 1): M Protein 3.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 48.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.28 mg/dL; Immunoglobulin G 70.5 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 9.87 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 11.5 g/dL; Glucose 4.68 mmol/L.
- Day 60 (ECOG 1): M Protein 0.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.956 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.683 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 9.27 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 150 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 14.5 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 10.4 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 4.73 mmol/L.
- Day 266 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.17 µg/mL; Lactate Dehydrogenase 10.1 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Glucose 4.73 mmol/L.
- Day 336 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 79.6 µmol/L; Total Protein 7.4 g/dL.
- Day 427 (ECOG 1): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 6.23 µg/mL; Lactate Dehydrogenase 10.6 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 4.57 mmol/L.
- Day 532 (ECOG 1): M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 0.44 µg/mL; Lactate Dehydrogenase 10.3 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 4.73 mmol/L.
- Day 623 (ECOG 1): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.179 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.107 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 9.29 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Total Protein 7.6 g/dL; Glucose 4.4 mmol/L.
- Day 686 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.57 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 12.7 ×10⁹/L; Absolute Neutrophil 11.7 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 798 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 7.31 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 10.3 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Total Protein 6.6 g/dL; Glucose 7.04 mmol/L.
- Day 883 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.158 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.224 mg/dL; Immunoglobulin G 4.36 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 5.2 µg/mL; Lactate Dehydrogenase 13 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.45 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 9.24 mmol/L.
- Day 952 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.158 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.264 mg/dL; Immunoglobulin G 5.14 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 12.8 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 1.4 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 9.08 mmol/L.
- Day 1,044 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.089 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 5.64 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 9.44 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 5.6 g/dL; Glucose 7.92 mmol/L.
- Day 1,134 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 2.13 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 10.3 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 4.73 mmol/L.
- Day 1,225 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 3.35 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 12.4 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.
- Day 1,330 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.061 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 1.53 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 15 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 6.38 mmol/L.
- Day 1,421 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 1.09 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 11.9 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 12.7 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 5.06 mmol/L.
- Day 1,512 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.804 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.322 mg/dL; Immunoglobulin G 1.09 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 8.8 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 5.12 mmol/L.
- Day 1,575 (ECOG 1): Lactate Dehydrogenase 8.28 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 6.22 mmol/L.
- Day 1,645 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.186 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 9.2 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 1.2 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 10.7 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 14.7 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 1,736 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.204 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.233 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 1.45 g/L; Lactate Dehydrogenase 9.45 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 363 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 6.33 mmol/L.
- Day 1,932 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.234 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.136 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 1.82 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 12.8 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 335 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 3.85 mmol/L.

Other clinical attributes
- Day -28: Weight: 55 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1021_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -28 days.
- Sample MMRF_1021_2_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 623 days (1.7 years).
